Gene-level copy-number profile of tumor specimen TCGA-GC-A6I3-01A from TCGA case TCGA-GC-A6I3, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-GC-A6I3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.2872046c-5ec0-4085-afad-c4c5c90d5096.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GC-A6I3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c96dee60-8d1c-4088-924a-2120b2253863

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 68; copy number 1: 332; copy number 2: 17,407; copy number 3: 23,320; copy number 4: 14,686; copy number 5: 3,313; copy number 6: 95; copy number 7: 280; copy number 8: 33; copy number 10: 40; copy number 13: 114; copy number 20: 56; copy number 21: 5; copy number 25: 12; copy number 43: 22; copy number 90: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GC-A6I3-01A-11D-A31K-01): tumor purity 0.32, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–22,455,740, 60 genes (within-gene range 0–4): FOCAD, FOCAD-AS1, MIR491, SNORA30B, HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr22:48,489,553–49,266,080, 8 genes (within-gene range 0–2): TAFA5, Z84468.1, MIR4535, LINC01310, AL078622.1, Z82202.2, RPL35P8, Z82202.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 590 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:19,143,695–25,057,073, 79 genes, copy number 10–13 (broad region; genes not listed).
- chr6:25,061,796–25,181,745, 4 genes, copy number 10: AL133268.4, AL133268.1, AL590084.3, AL590084.1.
- chr6:103,583,135–107,824,317, 56 genes, copy number 20–25 (within-gene range 3–25): AL591387.1, AL590608.1, R3HDM2P2, NPM1P10, AL357522.1, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, AL096794.1, LINC02836, Z97206.1, AL591518.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12, SOBP, AL121957.1, AL096816.1, SCML4.
- chr7:30,167,804–30,504,841, 11 genes, copy number 20 (within-gene range 4–20): RPS27P16, AC007036.1, ZNRF2, MIR550A1, MIR550B1, AC006978.2, AC006978.1, LINC01176, NOD1, AC006027.1, GGCT.
- chr7:33,109,557–33,877,180, 1 gene, copy number 7 (within-gene range 4–7): BBS9.
- chr7:33,276,834–36,841,373, 61 genes, copy number 7–21 (broad region; genes not listed).
- chr7:36,919,357–36,919,432, 1 gene, copy number 21: MIR1200.
- chr7:47,252,139–55,572,988, 94 genes, copy number 13–43 (within-gene range 5–43) (broad region; genes not listed).
- chr8:36,764,445–38,704,855, 60 genes, copy number 8–90: RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1.
- chr8:38,744,020–38,744,131, 1 gene, copy number 8: Y_RNA.
- chr10:73,495,525–76,560,168, 75 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr17:27,333,241–29,707,090, 141 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr17:29,639,627–29,645,847, 3 genes, copy number 7: AC104564.1, RNU6-920P, AC104564.5.
- chr17:33,052,107–33,131,743, 3 genes, copy number 7: AC003687.1, AC008133.2, AC008133.1.

Autosomal genes at a single copy (total copy number 1): 332. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
